Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84G, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84G-01A (Primary Tumor).

[page 1 of 2]
Patient Results

Anatomical Pathology results performed since

Corrected Results

Final Updated

LAB. NO.

ADDRESS :

DOCTOR :

SEX :

WARD :

D.O.B. :

REQUEST DATE :

DATE RECEIVED :

CONSULTANT :

SUPPLEMENTARY REPORT

SPECIMEN:

- A. Right frontal lesion.
- B. Right frontal brain tumour.
- C. Posterior margin resection.

Representative formalin fixed paraffin embedded tissue sections were submitted for FISH [fluorescence in situ hybridization] studies to assess 1p, 19q and EGFR. The FISH studies were performed in the

The FISH studies (which have been reported separately) demonstrated evidence of both 1p and 19q deletions. EGFR amplification was not detected. The original diagnosis of WHO grade III anaplastic oligodendroglioma remains unchanged.

PATHOLOGIST:

DOCTOR REVIEWING:

DATED:

ELECTRONICALLY VALIDATED:

----- END OF REPORT FOR -----

LAB. NO.

PATIENT

ADDRESS :

DOCTOR :

SEX :

WARD :

D.O.B. :

REQUEST DATE :

DATE RECEIVED :

CONSULTANT :

SPECIMEN:

- A. Right frontal lesion.
- B. Right frontal brain tumour.
- C. Posterior margin resection.

CLINICAL :

Right frontal lesion.

MACROSCOPIC:

- A. Three pieces of tan tissue 7 x 8 x 14mm in maximum dimension.

BLOCK KEY:

1: frozen piece, 2: remainder of specimen

INTRA-OPERATIVE ASSESMENT - FROZEN SECTION

Glioma, probably oligodendroglioma.

- B. Pale brain parenchyma measuring 35 x 35 x 25mm. The entire specimen embedded.

- C. Four pale pieces of soft tissue 3 - 8mm in maximum dimensions. All embedded.

MICROSCOPIC:

A. and B. All tissue submitted was processed and examined. Study of the sections confirms the intraoperative findings. The sections include cortex and white matter, extensively effaced by formations of a diffuse oligodendroglioma neoplasm. In many areas the oligodendroglioma has low grade appearances, where it involves both cortex and white matter, and demonstrates "classical" oligodendroglial morphology. In addition, however, there are areas of markedly increased cellularity and increasing pleomorphism, associated with microvascular endothelial proliferation. Mitotic and apoptotic activity are evident within

100-3
Oligodendroglioma, grade III 9451/3
Site Brain neoplasms NOS 271.0
pt. Verain, frontal lobe 271.1
9/19/2013

Requested by:

Printed from:

[page 2 of 2]
ent Results
nts - Performed since

Corrected Results

these microscopic foci, with single high power microscopic fields containing as many as three mitotic figures. Maximal mitotic counts are eight mitotic figures per 10 high power fields. The proliferation index, as judged by immunohistochemical staining with the proliferation marker MIB 1, is variable, but is markedly increased within the hypercellular and mitotically active fields described of, where it approaches the order of 10% focally. There is scattered weak to moderate nuclear positivity for p53 protein. Considered in combination, these morphological findings [mitotic counts greater than five figures per 10 high power fields, hypercellularity and pleomorphism, microvascular endothelial proliferation] are consistent with WHO grade III [anaplastic] oligodendroglioma. C. All tissue submitted was processed and examined. Sections include cortex and white matter, demonstrating some reactive changes. No unequivocal areas of glioma involvement evident in the material examined.

CONCLUSION:

- A. and B. Right frontal brain tumor. WHO grade III [anaplastic] oligodendroglioma.
- C. Posterior margin resection. Reactive cortex and white matter; - no definite glioma identified.
- Representative formalin fixed paraffin embedded tissue sections will be submitted for FISH [fluorescence in situ hybridization] studies to assess 1p, 19q and EGFR. These results will be reported separately.

REGISTRAR:

PATHOLOGIST:
DOCTOR REVIEWING:

DATED:
ELECTRONICALLY VALIDATED:

----- END OF REPORT FOR -----

Requested by

Source: NCI Genomic Data Commons file ca10493e-2372-4fbb-be18-7f55f142b484 (TCGA-TM-A84G.FC215743-E198-46BB-A098-804629994BD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).